Surgical pathology report (de-identified scan), TCGA case TCGA-05-4424, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4424-01A (Primary Tumor).

Main diagnosis/diagnoses:

Locally advanced, peripheral bronchopulmonary, histologically mixed adenocarcinoma of the right upper lobe of the lung with an acinar and solid component, slight mucin formation and localization in S1 and S2.

TNM classification on the basis of this material pT3 pN0 pMX V1 R1, stage IIB.
C34.1 M8255/3.

Comment/supplementary remark:

The carcinoma has spread into the adhesive part of the chest wall, where it has infiltrated both the soft tissue and the 3rd rib, extending in a circumscribed manner as far as the outer resection surface at the thoracic skin, which explains the R1 classification. The carcinoma has also spread as far as the visceral pleura of the adhesive part evidently from S6 of the upper lobe. The resection margin of the bronchus and vessels, the other resection margins of the resected chest wall material, the lung parenchyma of the resection material evidently taken from S6 and all the lymph nodes identified and removed are tumor-free.

Source: NCI Genomic Data Commons file 20fb64e6-fca9-4d45-8647-b089ce1c50c8 (TCGA-05-4424.DA7DFF31-ACBB-4D15-B607-E3C0A4FA5901.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).